Gene-level copy-number profile of tumor specimen TCGA-BR-8686-01A from TCGA case TCGA-BR-8686, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 69.5 years (25,372 days).
Specimen TCGA-BR-8686-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.4903dd82-cc98-4806-8f64-847c9d115f9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8686-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0b302787-f47f-40f6-90b7-c9dbc747abe6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,215; copy number 3: 51,380; copy number 4: 182; copy number 6: 11; copy number 8: 9; copy number 9: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8686-01A-11D-2390-01): tumor purity 0.28, ploidy 4.02, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 32 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:32,602,246–33,105,943, 9 genes, copy number 8 (within-gene range 4–8): CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294.
- chr11:34,915,829–35,918,739, 19 genes, copy number 9: PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1.
- chr11:35,967,010–36,010,204, 4 genes, copy number 9: AL136146.1, AL136146.2, RPL12P31, MIR3973.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
